Surgical pathology report (de-identified scan), TCGA case TCGA-UZ-A9PU, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University of California San Francisco, specimen TCGA-UZ-A9PU-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]
Med. Rec. #: [REDACTED] Visit #: [REDACTED]
DOB: [REDACTED] Sex: Male
Soc. Sec. #: [REDACTED] Location: [REDACTED]
Physician(s): [REDACTED]

Accession #: [REDACTED]
Service Date: [REDACTED]
Received: [REDACTED]
Client: [REDACTED]

FINAL PATHOLOGIC DIAGNOSIS

Kidney, right, partial nephrectomy: Papillary renal cell carcinoma, 5.8 cm; see comment.

COMMENT:

Kidney Tumor Synoptic Comment

- **Histologic type:** Papillary renal cell carcinoma, Type 1.
- **Grade:** Fuhrman grading for RCC: grade 2.
- **Tumor size:** 5.8 x 4.5 x 3.3 cm.
- **Site within kidney:** Mid to inferior pole of right kidney.
- **Renal pelvis:** NA.
- **Ureter:** NA.
- **Renal sinus:** NA.
- **Hilar renal veins:** NA.
- **Intrarenal veins and lymphatics:** No tumor.
- **Adrenal gland:** NA
- **Capsule/perirenal fat:** No tumor.
- **Lymph node status:** Not surgically sampled.
- **Resection margins:** Negative.
- **Ureter:** NA.
- **Renal vein:** NA.
- **Soft tissue:** Negative, 0.6 cm to perirenal fat margin.
- **Renal parenchyma:** Negative but close, less than 0.1 cm to margin.
- **Proximity to nearest margin:** Less than 0.1 cm.
- **AJCC Stage:** pT1bNXMX.

ICD-O-3
Carcinoma papillary
renal cell 8260/3
Site @ Kidney NOS C64.9
9/3/2014

Specimen(s) Received

A:Kidney, Partial Nephrectomy (fresh)

Intraoperative Diagnosis

[page 2 of 2]
[REDACTED]

A. Right kidney, gross evaluation: Tumor approaches the surgical margin by <1 mm. (Dr. [REDACTED])

Clinical History

The patient is a [REDACTED] year-old male who was discovered to have an incidental finding of a 4.6 cm enhancing renal mass on the anterior aspect of the mid to inferior pole of the right kidney. The patient undergoes an open partial right nephrectomy.

Gross Description

The specimen is received in formalin in one part, labeled with the patient's name, medical record number and "right partial nephrectomy," and consists of an unoriented ovoid apparent renal tissue that is firm, and a soft apparent fat tissue. The total specimen measures 9.2 x 4.6 x 4.5 cm. The ovoid renal tissue measures 6.2 x 4.5 x 3.8 cm and the fat tissue measures 9.2 x 3.5 x 0.5 cm. The specimen was received with all margins inked black and has been serially sectioned. The renal mass abuts the surgical margin and occupies approximately 90% of the renal tissue. The mass is ovoid and soft, tan-white, and measures 5.8 x 4.5 x 3.3 cm. There is a red-brown region of apparent necrosis/hemorrhage, measuring 3.1 x 2.7 x 2.5 cm, within the renal mass. A thin rim of apparent renal parenchyma surrounds the mass, with the thickest depth measuring 0.9 cm. The perirenal fat is soft and unremarkable. Representative sections are submitted as follows:

Cassette A1: Renal mass with resection margin, two sections.

Cassette A2: Renal mass showing relationship to inked perirenal fat, two sections.

Cassette A3: Renal mass showing relationship to inked perirenal fat, one section.

Cassette A4: Renal mass/necrosis, one section.

Cassette A5:

Apparent normal renal

parenchyma, one section.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

[REDACTED] Pathology Resident

[REDACTED] Pathologist

Electronically signed out on [REDACTED]

Source: NCI Genomic Data Commons file 08c12e9e-cd48-4d75-9732-95556df020d3 (TCGA-UZ-A9PU.5FD45A76-33F6-47BA-A9EC-0AF6A7E28B5E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).